Somatic mutation profile of tumor specimen SM-JU356 (aliquot 7316UP-1640) from CPTAC case C685110, project CPTAC-3 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Intraductal carcinoma, NOS; Tissue or organ of origin: Breast, NOS.
Specimen SM-JU356: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a652711-c1be-49b0-a24c-a87954880323.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105277 (Blood Derived Normal), aliquot 7316UP-1640-1105277; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/919edc7f-f451-4998-ad4a-526f1f45e983

The open-access MAF lists 151 somatic variants for this specimen: 109 protein-altering or splice-affecting, 23 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 23, Frame Shift Del 19, Nonsense Mutation 8, Splice Site 7, Intron 7, 5'UTR 6, In Frame Del 4, Splice Region 3, Frame Shift Ins 3, RNA 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.1358_1359del p.K453Rfs*15 | Frame Shift Del (DEL) | VAF 88/180 reads (49%) | catalogued as rs1351986946; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA10 | c.2313del p.R772Efs*8 | Frame Shift Del (DEL) | VAF 129/359 reads (36%) | catalogued as COSV52226795; called by mutect2, pindel, varscan2
- ACTL8 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 37/45 reads (82%) | catalogued as rs929124190; called by muse, mutect2, varscan2
- ANXA13 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 65/191 reads (34%) | catalogued as COSV51625648; called by muse, mutect2, varscan2
- EHD2 | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV54407896, COSV99621506; called by muse, mutect2, varscan2
- EXOC3L2 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 100/288 reads (35%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.546); catalogued as rs146408436, COSV99374660; called by muse, mutect2, varscan2
- FTHL17 | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV63266312; called by muse, mutect2
- GMDS | c.1005C>G p.D335E | Missense Mutation (SNP) | VAF 82/228 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.305); catalogued as COSV101070491; called by muse, mutect2, varscan2
- HOXA10 | c.946_948del p.K316del | In Frame Del (DEL) | VAF 432/861 reads (50%) | catalogued as rs1264111265; called by mutect2, pindel, varscan2
- IFT172 | c.5093T>C p.I1698T | Missense Mutation (SNP) | VAF 79/216 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs762114339, COSV99274945; called by muse, mutect2, varscan2
- IGKV1-8 | c.194A>G p.K65R | Missense Mutation (SNP) | VAF 34/652 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as rs759609764; called by muse, mutect2
- ITGAV | c.2706+7G>A | Splice Region (SNP) | VAF 234/281 reads (83%) | catalogued as rs776851066, COSV53719519; called by muse, mutect2, varscan2
- LRRC6 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs189293241, COSV51538239; called by muse, mutect2, varscan2
- MAP4K1 | c.2341-7del | Splice Region (DEL) | VAF 67/177 reads (38%) | catalogued as rs767461672, COSV101204269; called by mutect2, pindel, varscan2
- MRPS18B | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 160/355 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs116524936; called by muse, mutect2, varscan2
- MSLNL | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 160/329 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs766186362; called by muse, mutect2, varscan2
- PRDM16 | c.2851T>A p.Y951N | Missense Mutation (SNP) | VAF 80/103 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99578259; called by muse, mutect2, varscan2
- PRSS53 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs778137757, COSV99762745; called by muse, mutect2, varscan2
- RAD54L2 | c.1812C>G p.S604R | Missense Mutation (SNP) | VAF 121/164 reads (74%) | SIFT tolerated (0.05); PolyPhen benign (0.251); catalogued as COSV56582303; called by muse, mutect2, varscan2
- RANBP3 | c.1473G>A p.S491= (on ENST00000340578 / NM_007322.3; = p.S486= on NM_003624.3) | Splice Region (SNP) | VAF 53/170 reads (31%) | catalogued as rs1012413726, COSV50382238; called by muse, mutect2, varscan2
- RASAL3 | c.2972C>A p.T991K | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.535); catalogued as COSV54604678; called by muse, mutect2, varscan2
- RASEF | c.1029-1G>A p.X343_splice | Splice Site (SNP) | VAF 408/588 reads (69%) | catalogued as rs1444601094, COSV100907060; called by muse, mutect2, varscan2
- SUGP1 | c.1822C>T p.R608W | Missense Mutation (SNP) | VAF 181/432 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs747643478, COSV55920060, COSV99895724; called by muse, mutect2, varscan2
- SULT1A1 | c.854C>A p.A285E | Missense Mutation (SNP) | VAF 136/583 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs746968899; called by muse, mutect2, varscan2
- TNR | c.3593G>A p.R1198H | Missense Mutation (SNP) | VAF 174/234 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs368661657, COSV54873347; called by muse, mutect2, varscan2
- TP53 | c.944_945insCC p.P316Lfs*30 | Frame Shift Ins (INS) | VAF 117/220 reads (53%) | catalogued as COSV53220710; called by mutect2, pindel, varscan2
- TUSC2 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 49/68 reads (72%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs1553717633; called by muse, mutect2, varscan2
- ZNF292 | c.7081C>T p.R2361C | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs376564177; called by muse, mutect2, varscan2
- ADAMTS18 | c.1841_1842del p.R614Tfs*4 | Frame Shift Del (DEL) | VAF 180/609 reads (30%) | called by pindel, varscan2
- ADAP1 | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 536/588 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- AGO2 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 70/219 reads (32%) | called by muse, mutect2, varscan2
- ANGPT2 | c.1032+2_1032+35del p.X344_splice | Splice Site (DEL) | VAF 50/70 reads (71%) | called by mutect2, pindel
- ANKRD36 | c.2887-1G>T p.X963_splice | Splice Site (SNP) | VAF 101/504 reads (20%) | called by muse, mutect2, varscan2
- ARHGAP35 | c.1731del p.F578Lfs*50 | Frame Shift Del (DEL) | VAF 76/207 reads (37%) | called by mutect2, pindel, varscan2
- ASB2 | c.1114G>T p.V372F | Missense Mutation (SNP) | VAF 229/276 reads (83%) | SIFT tolerated (0.72); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATPAF1 | c.589-3_589-2del p.X197_splice (on ENST00000574428; = p.X220_splice on NM_022745.4) | Splice Site (DEL) | VAF 64/190 reads (34%) | called by pindel, varscan2
- BIRC2 | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 65/189 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- C2orf73 | c.343_368del p.L115Kfs*33 | Frame Shift Del (DEL) | VAF 44/195 reads (23%) | called by mutect2, pindel
- CFAP46 | c.1595A>G p.N532S | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2
- COL4A3 | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 185/270 reads (69%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- COL9A1 | c.1835C>A p.P612Q | Missense Mutation (SNP) | VAF 345/813 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CSF3R | c.944C>G p.P315R | Missense Mutation (SNP) | VAF 324/424 reads (76%) | SIFT tolerated (0.29); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DHX9 | c.3346A>C p.K1116Q | Missense Mutation (SNP) | VAF 95/419 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DLC1 | c.3992G>T p.G1331V (on ENST00000276297 / NM_001348081.2; = p.G894V on NM_006094.5) | Missense Mutation (SNP) | VAF 98/146 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DMD | c.9500A>G p.N3167S | Missense Mutation (SNP) | VAF 267/637 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- DNAH17 | c.4681G>A p.A1561T | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- EAPP | c.402_411del p.D135Cfs*42 | Frame Shift Del (DEL) | VAF 54/273 reads (20%) | called by mutect2, pindel, varscan2
- ENDOD1 | c.462G>C p.Q154H | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ENPEP | c.773A>T p.N258I | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERRFI1 | c.488_491del p.S163Wfs*11 | Frame Shift Del (DEL) | VAF 248/345 reads (72%) | called by mutect2, pindel, varscan2
- EVI2B | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- FAM181B | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FER1L5 | c.5383_5385del p.K1795del (on ENST00000623019; = p.K1759del on NM_001293083.2) | In Frame Del (DEL) | VAF 93/235 reads (40%) | called by mutect2, pindel, varscan2
- GAS6 | c.900G>T p.M300I | Missense Mutation (SNP) | VAF 295/363 reads (81%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- GBA | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 80/266 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- GLIPR1L2 | c.481-1G>C p.X161_splice | Splice Site (SNP) | VAF 61/87 reads (70%) | called by muse, mutect2, varscan2
- GPAA1 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 175/610 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- GRIA2 | c.19A>G p.I7V | Missense Mutation (SNP) | VAF 64/87 reads (74%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRIK4 | c.190G>T p.V64F | Missense Mutation (SNP) | VAF 246/296 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- KDF1 | c.1135T>C p.S379P | Missense Mutation (SNP) | VAF 202/259 reads (78%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- LCA5 | c.526A>G p.R176G | Missense Mutation (SNP) | VAF 21/445 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- LRRC45 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 161/520 reads (31%) | called by muse, mutect2, varscan2
- MBD5 | c.2419_2432del p.L807Tfs*19 | Frame Shift Del (DEL) | VAF 52/85 reads (61%) | called by mutect2, pindel, varscan2
- MROH2A | c.605_621del p.L202Hfs*7 | Frame Shift Del (DEL) | VAF 31/294 reads (11%) | called by mutect2, pindel
- MS4A12 | c.620T>C p.M207T | Missense Mutation (SNP) | VAF 125/338 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC22 | c.2770G>A p.E924K | Missense Mutation (SNP) | VAF 169/382 reads (44%) | SIFT tolerated (0.25); called by muse, mutect2, varscan2
- MXRA5 | c.1944C>A p.Y648* | Nonsense Mutation (SNP) | VAF 57/126 reads (45%) | called by muse, mutect2, varscan2
- NCAN | c.3300_3319del p.Y1100* | Frame Shift Del (DEL) | VAF 107/488 reads (22%) | called by mutect2, pindel, varscan2
- NECTIN2 | c.1316A>T p.Y439F | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NFKBIE | c.484_485del p.L162Afs*47 (on ENST00000275015; = p.L23Afs*47 on NM_004556.3) | Frame Shift Del (DEL) | VAF 244/760 reads (32%) | called by pindel, varscan2
- OR5I1 | c.425T>C p.I142T | Missense Mutation (SNP) | VAF 99/276 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR8G2P | c.836C>A p.T279N | Missense Mutation (SNP) | VAF 92/249 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); called by mutect2, varscan2
- PDE5A | c.2058dup p.D687* | Frame Shift Ins (INS) | VAF 44/126 reads (35%) | called by pindel, varscan2
- PEG3 | c.2177G>T p.G726V | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGRMC2 | c.81T>A p.S27R | Missense Mutation (SNP) | VAF 162/391 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PHLDA1 | c.821_856del p.A274_R286delinsG | In Frame Del (DEL) | VAF 92/146 reads (63%) | called by mutect2, pindel
- PI4K2A | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 127/197 reads (64%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIK3R1 | c.1132_1172del p.N378Lfs*3 (on ENST00000521381 / NM_181523.3; = p.N108Lfs*3 on NM_181504.4) | Frame Shift Del (DEL) | VAF 50/70 reads (71%) | called by mutect2, pindel
- PKHD1L1 | c.3740C>A p.P1247Q | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PNLIPRP1 | c.1-1G>C p.X1_splice | Splice Site (SNP) | VAF 41/133 reads (31%) | called by muse, mutect2, varscan2
- POU5F1 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 24/337 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPP2R3B | c.1155dup p.D386Rfs*65 | Frame Shift Ins (INS) | VAF 86/278 reads (31%) | called by mutect2, pindel, varscan2
- PRCC | c.75G>C p.E25D | Missense Mutation (SNP) | VAF 214/675 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM15 | c.3442A>T p.T1148S | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- PSIP1 | c.1417A>G p.T473A | Missense Mutation (SNP) | VAF 187/227 reads (82%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- R3HDM1 | c.2617G>A p.D873N | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- RIPK4 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 11/236 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RNF40 | c.1899G>C p.R633S | Missense Mutation (SNP) | VAF 93/230 reads (40%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RPS6KA3 | c.2064C>A p.Y688* | Nonsense Mutation (SNP) | VAF 246/633 reads (39%) | called by muse, mutect2, varscan2
- SAGE1 | c.1753_1762del p.E585Kfs*29 | Frame Shift Del (DEL) | VAF 105/167 reads (63%) | called by mutect2, pindel, varscan2
- SLC17A4 | c.1406T>C p.V469A | Missense Mutation (SNP) | VAF 85/237 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- SMARCC1 | c.2646+1G>A p.X882_splice | Splice Site (SNP) | VAF 66/87 reads (76%) | called by muse, varscan2
- SMTNL1 | c.719A>G p.E240G (on ENST00000399154; = p.E277G on NM_001105565.2) | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SPIRE2 | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 157/460 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- STK24 | c.462_463del p.H154Qfs*4 | Frame Shift Del (DEL) | VAF 66/116 reads (57%) | called by pindel, varscan2
- STX3 | c.772_773del p.Q259Gfs*35 | Frame Shift Del (DEL) | VAF 57/208 reads (27%) | called by pindel, varscan2
- TBX21 | c.1296G>A p.W432* | Nonsense Mutation (SNP) | VAF 150/367 reads (41%) | called by muse, mutect2, varscan2
- TDRD15 | c.805A>T p.N269Y | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- TERF2 | c.56del p.D19Afs*140 | Frame Shift Del (DEL) | VAF 61/197 reads (31%) | called by mutect2, pindel, varscan2
- TMEM38B | c.4G>C p.D2H | Missense Mutation (SNP) | VAF 145/405 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- TMPRSS7 | c.1672C>T p.P558S (on ENST00000452346; = p.P432S on NM_001042575.2) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- TOP1 | c.475_477del p.K159del | In Frame Del (DEL) | VAF 10/52 reads (19%) | called by pindel, varscan2
- TRIM9 | c.1073T>G p.V358G | Missense Mutation (SNP) | VAF 104/147 reads (71%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP21 | c.1021G>T p.G341W | Missense Mutation (SNP) | VAF 78/204 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VAT1L | c.789_790del p.L265Sfs*43 | Frame Shift Del (DEL) | VAF 60/270 reads (22%) | called by mutect2, pindel, varscan2
- ZFAND3 | c.396del p.K132Nfs*75 | Frame Shift Del (DEL) | VAF 10/108 reads (9%) | called by mutect2, pindel
- ZFP82 | c.760T>G p.Y254D | Missense Mutation (SNP) | VAF 143/375 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZIM3 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 96/286 reads (34%) | called by muse, mutect2
- ZNF483 | c.2134del p.I712Ffs*61 | Frame Shift Del (DEL) | VAF 67/357 reads (19%) | called by mutect2, pindel, varscan2
- ACACB | c.3522C>T p.H1174= | Silent (SNP) | VAF 65/92 reads (71%) | catalogued as rs1032042057, COSV58143745; called by muse, mutect2, varscan2
- ACSM2B | c.1662C>A p.V554= | Silent (SNP) | VAF 69/209 reads (33%) | called by muse, mutect2, varscan2
- BIRC2 | c.1086T>C p.T362= | Silent (SNP) | VAF 6/119 reads (5%) | called by muse, mutect2
- CARD10 | c.873G>T p.T291= | Silent (SNP) | VAF 97/333 reads (29%) | called by muse, mutect2
- CORO7 | c.237A>G p.L79= | Silent (SNP) | VAF 58/239 reads (24%) | called by muse, mutect2, varscan2
- CYSRT1 | c.414C>G p.A138= (on ENST00000409414; = p.A98= on NM_199001.5) | Silent (SNP) | VAF 201/263 reads (76%) | called by muse, mutect2, varscan2
- DNAH17 | c.9747C>G p.V3249= | Silent (SNP) | VAF 64/1002 reads (6%) | called by muse, mutect2
- EFHC2 | c.477C>T p.V159= | Silent (SNP) | VAF 68/174 reads (39%) | called by muse, mutect2, varscan2
- FAT1 | c.3846C>A p.G1282= | Silent (SNP) | VAF 121/186 reads (65%) | called by muse, mutect2, varscan2
- GRIN3B | c.621G>C p.R207= | Silent (SNP) | VAF 97/127 reads (76%) | called by muse, mutect2, varscan2
- IFT81 | c.42G>A p.K14= | Silent (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- IQSEC2 | c.1779G>C p.L593= (on ENST00000642864 / NM_001111125.3; = p.L388= on NM_015075.2) | Silent (SNP) | VAF 136/371 reads (37%) | called by muse, mutect2, varscan2
- KSR2 | c.1683G>T p.L561= | Silent (SNP) | VAF 50/80 reads (63%) | called by muse, mutect2, varscan2
- PCDH8 | c.291C>T p.G97= | Silent (SNP) | VAF 168/418 reads (40%) | catalogued as COSV100131369; called by muse, mutect2, varscan2
- PTK2B | c.1293T>G p.L431= | Silent (SNP) | VAF 11/146 reads (8%) | called by muse, mutect2
- RIN1 | c.2148G>A p.E716= | Silent (SNP) | VAF 101/242 reads (42%) | called by muse, mutect2, varscan2
- SCRN1 | c.27T>C p.C9= | Silent (SNP) | VAF 172/322 reads (53%) | called by muse, mutect2, varscan2
- SLC9A4 | c.1014C>T p.Y338= | Silent (SNP) | VAF 114/308 reads (37%) | catalogued as rs765936170; called by muse, mutect2, varscan2
- TMEM64 | c.288C>G p.G96= | Silent (SNP) | VAF 49/305 reads (16%) | catalogued as COSV69127712; called by muse, mutect2, varscan2
- USP35 | c.537C>G p.A179= | Silent (SNP) | VAF 144/273 reads (53%) | called by muse, mutect2, varscan2
- WDFY4 | c.4272C>G p.L1424= | Silent (SNP) | VAF 89/113 reads (79%) | called by muse, mutect2, varscan2
- ZBP1 | c.453C>T p.H151= | Silent (SNP) | VAF 118/290 reads (41%) | called by muse, mutect2, varscan2
- ZMYM1 | c.210A>G p.S70= | Silent (SNP) | VAF 66/88 reads (75%) | called by muse, varscan2
- AC008758.3 | n.486_487del | RNA (DEL) | VAF 76/242 reads (31%) | called by pindel, varscan2
- AC106795.1 | n.964+50T>C | Intron (SNP) | VAF 23/61 reads (38%) | called by mutect2, varscan2
- AC136777.1 | n.272T>A | RNA (SNP) | VAF 18/189 reads (10%) | called by muse, mutect2
- ANKRD30A | c.2156-3577G>A | Intron (SNP) | VAF 18/116 reads (16%) | catalogued as rs1276733733; called by mutect2, varscan2
- CAMTA1 | c.*34T>A | 3'UTR (SNP) | VAF 15/119 reads (13%) | called by muse, mutect2
- CAPN1 | chr11:65214129 G>C | 3'Flank (SNP) | VAF 165/417 reads (40%) | called by muse, mutect2, varscan2
- CCNB1IP1 | c.-23dup | 5'UTR (INS) | VAF 33/98 reads (34%) | called by mutect2, pindel, varscan2
- CCT3 | c.304+355G>A | Intron (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- DECR2 | c.-47C>G | 5'UTR (SNP) | VAF 74/207 reads (36%) | catalogued as rs906429270; called by muse, mutect2, varscan2
- DRD2 | c.-11C>G | 5'UTR (SNP) | VAF 120/328 reads (37%) | called by muse, mutect2, varscan2
- FAM117B | c.-4del | 5'UTR (DEL) | VAF 12/28 reads (43%) | catalogued as rs927921762; called by mutect2, varscan2
- GZMK | c.-45_-30del | 5'UTR (DEL) | VAF 24/58 reads (41%) | called by mutect2, pindel
- MRPL10 | c.52+38G>A | Intron (SNP) | VAF 140/323 reads (43%) | catalogued as rs1462377202; called by muse, mutect2, varscan2
- NCOA3 | c.-16C>G | 5'UTR (SNP) | VAF 21/70 reads (30%) | called by muse, mutect2, varscan2
- RAVER1 | c.1432-20G>A | Intron (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
- RFK | chr9:76398726 A>T | 5'Flank (SNP) | VAF 18/594 reads (3%) | called by muse, mutect2
- RIN2 | c.112-25C>G | Intron (SNP) | VAF 105/259 reads (41%) | called by muse, mutect2, varscan2
- RTN1 | c.1766-23029C>A | Intron (SNP) | VAF 93/126 reads (74%) | catalogued as rs373783767; called by muse, mutect2, varscan2
- TBC1D29P | n.2468C>T | RNA (SNP) | VAF 245/315 reads (78%) | called by muse, mutect2, varscan2
